Somatic mutation profile of tumor specimen 0DBHZC from CCDI case PBBLEG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,672 days).
Specimen 0DBHZC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 417db33b-5aef-4a02-b618-23167a0032be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBHZ6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c602557-aec1-43c5-8900-00f0580c4813

The open-access MAF lists 16,053 somatic variants for this specimen: 9,659 protein-altering or splice-affecting, 3,220 silent, 3,174 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,370, Silent 3,220, Intron 1,791, 3'UTR 655, Nonsense Mutation 561, 5'UTR 462, Splice Site 283, Splice Region 239, 5'Flank 111, Frame Shift Del 106, Frame Shift Ins 78, 3'Flank 77.

Variants (750 of 16,053; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219del p.R74Gfs*23 | Frame Shift Del (DEL) | VAF 102/390 reads (26%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, varscan2
- AHI1 | c.2156A>G p.D719G | Missense Mutation (SNP) | VAF 137/659 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs863225134, CM060808; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APOB | c.3997C>T p.R1333* | Nonsense Mutation (SNP) | VAF 195/418 reads (47%) | catalogued as rs121918383, CM880006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 33/104 reads (32%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, varscan2
- COL18A1 | c.3988C>T p.R1330* (on ENST00000359759 / NM_130444.3; = p.R1095* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 37/154 reads (24%) | catalogued as rs753824908; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DDHD2 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 79/437 reads (18%) | catalogued as rs201258800; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYSF | c.1642del p.X548_splice | Splice Site (DEL) | VAF 64/179 reads (36%) | catalogued as rs398123772; ClinVar: pathogenic; called by mutect2, varscan2
- EIF1AX | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 54/364 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV63309291, COSV63309392, COSV63309466; called by muse, mutect2, varscan2
- GAA | c.2242dup p.E748Gfs*48 | Frame Shift Ins (INS) | VAF 34/293 reads (12%) | catalogued as rs777275355; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GRIK2 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 76/550 reads (14%) | catalogued as rs749995448, CM151336; ClinVar: pathogenic; called by muse, varscan2
- HIBCH | c.129dup p.G44Rfs*20 | Frame Shift Ins (INS) | VAF 74/412 reads (18%) | catalogued as rs767597690; ClinVar: pathogenic; called by mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 92/223 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- KIAA0586 | c.-8dup | 5'UTR (INS) | VAF 224/507 reads (44%) | catalogued as rs745949846; ClinVar: pathogenic; called by mutect2, varscan2
- MACF1 | c.21923G>A p.R7308H (on ENST00000372915; = p.R5353H on NM_012090.5) | Missense Mutation (SNP) | VAF 83/460 reads (18%) | catalogued as rs755081350, COSV57134020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.2047G>A p.G683R | Missense Mutation (SNP) | VAF 207/463 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267607995, CM085561, COSV51880988; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- OPLAH | c.2608dup p.H870Pfs*92 | Frame Shift Ins (INS) | VAF 40/157 reads (25%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2361dup p.T788Hfs*5 | Frame Shift Ins (INS) | VAF 38/179 reads (21%) | catalogued as rs770591449; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 125/477 reads (26%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 229/494 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLR1C | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 51/406 reads (13%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.764); catalogued as rs373046018, CM157296; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4547C>T p.S1516L (on ENST00000303395 / NM_001202435.3; = p.S1505L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/492 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs139300715, CM024310, CM1511239, COSV57665028; ClinVar: uncertain significance / likely benign / likely pathogenic; called by muse, mutect2, varscan2
- SCNN1A | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 104/419 reads (25%) | catalogued as rs137852634, CM961266; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SNX14 | c.1108G>T p.E370* (on ENST00000314673 / NM_001350535.1; = p.E326* on NM_020468.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 57/536 reads (11%) | catalogued as rs201128942; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 145/349 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TWNK | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 115/250 reads (46%) | catalogued as rs863223919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZEB2 | c.674C>A p.S225* | Nonsense Mutation (SNP) | VAF 95/438 reads (22%) | catalogued as rs797046122; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 126/259 reads (49%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- A1BG | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs375666222, COSV104370829; called by muse, mutect2, varscan2
- AADACL4 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 91/343 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1486266827; called by muse, mutect2, varscan2
- AAR2 | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 106/522 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV100299490; called by muse, varscan2
- AARS1 | c.2785G>T p.G929C | Missense Mutation (SNP) | VAF 69/444 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750827192; called by muse, mutect2, varscan2
- AARS1 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 46/418 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV55747457; called by muse, mutect2, varscan2
- AASS | c.2681G>T p.G894V | Missense Mutation (SNP) | VAF 245/516 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs893073236; called by mutect2, varscan2
- AATK | c.1597C>T p.R533C (on ENST00000326724 / NM_001080395.3; = p.R430C on NM_004920.2) | Missense Mutation (SNP) | VAF 53/387 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99044951; called by muse, mutect2, varscan2
- AATK | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 85/472 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs373920229; called by muse, mutect2, varscan2
- ABAT | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 79/391 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV51627612; called by muse, mutect2, varscan2
- ABCA13 | c.12064C>T p.R4022* | Nonsense Mutation (SNP) | VAF 142/296 reads (48%) | catalogued as rs773961513, COSV71287919, COSV71297217; called by muse, mutect2, varscan2
- ABCA2 | c.2641G>A p.A881T (on ENST00000614293; = p.A851T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/406 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1396280548, COSV99687164; called by muse, mutect2, varscan2
- ABCA4 | c.5048C>T p.A1683V | Missense Mutation (SNP) | VAF 89/436 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1402394753, COSV64672655; called by muse, mutect2, varscan2
- ABCA4 | c.4622T>C p.L1541P | Missense Mutation (SNP) | VAF 118/522 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as CM159386; called by muse, varscan2
- ABCA4 | c.4603G>T p.V1535L | Missense Mutation (SNP) | VAF 126/570 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV64674601; called by muse, varscan2
- ABCA5 | c.3024C>A p.F1008L | Missense Mutation (SNP) | VAF 54/378 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs762294982; called by muse, mutect2, varscan2
- ABCA5 | c.1933A>T p.M645L | Missense Mutation (SNP) | VAF 116/741 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs746487074; called by muse, mutect2, varscan2
- ABCB6 | c.911G>A p.W304* | Nonsense Mutation (SNP) | VAF 78/462 reads (17%) | catalogued as rs1490856072; called by muse, mutect2, varscan2
- ABCC10 | c.847C>T p.R283W (on ENST00000372530 / NM_001198934.2; = p.R240W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/250 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs376319036; called by muse, mutect2, varscan2
- ABCC10 | c.2014G>T p.E672* (on ENST00000372530 / NM_001198934.2; = p.E644* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/562 reads (5%) | catalogued as COSV55089265; called by muse, mutect2
- ABCC10 | c.3508G>A p.A1170T (on ENST00000372530 / NM_001198934.2; = p.A1142T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs371782757; called by muse, mutect2, varscan2
- ABCC12 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 101/419 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as rs368065021; called by muse, mutect2, varscan2
- ABCC4 | c.3608C>T p.A1203V | Missense Mutation (SNP) | VAF 72/408 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373949612; called by muse, mutect2, varscan2
- ABCC5 | c.3481G>T p.E1161* | Nonsense Mutation (SNP) | VAF 84/382 reads (22%) | catalogued as COSV55588886; called by muse, mutect2, varscan2
- ABCC6 | c.1082G>T p.C361F | Missense Mutation (SNP) | VAF 91/590 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as COSV52741818; called by muse, mutect2, varscan2
- ABCC9 | c.3808G>A p.A1270T | Missense Mutation (SNP) | VAF 61/357 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.901); catalogued as COSV99686359; called by muse, mutect2, varscan2
- ABCC9 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 153/704 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV53973588; called by muse, mutect2, varscan2
- ABCF2 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 103/548 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55184103; called by muse, mutect2, varscan2
- ABHD16B | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1392566977; called by muse, varscan2
- ABHD16B | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 108/243 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771232001; called by muse, varscan2
- ABI3BP | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 83/407 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs761557013; called by muse, mutect2, varscan2
- ABL1 | c.2804C>T p.T935M | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs143811852; called by muse, mutect2, varscan2
- ABL2 | c.2160dup p.S721Efs*9 (on ENST00000502732 / NM_007314.4; = p.S706Efs*9 on NM_005158.5) | Frame Shift Ins (INS) | VAF 21/190 reads (11%) | catalogued as rs771692956; called by mutect2, varscan2
- ABR | c.724C>T p.R242W (on ENST00000302538 / NM_021962.5; = p.R205W on NM_001092.5) | Missense Mutation (SNP) | VAF 133/285 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567704830; called by muse, varscan2
- AC005324.2 | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV60885932; called by muse, mutect2
- AC068580.4 | c.312G>T p.W104C | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99362430; called by muse, mutect2, varscan2
- ACACA | c.6710G>A p.G2237D | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1422491925; called by muse, mutect2
- ACACA | c.5425G>A p.V1809M | Missense Mutation (SNP) | VAF 194/436 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1167506850; called by muse, varscan2
- ACAD8 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 83/593 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55542514; called by muse, mutect2, varscan2
- ACADM | c.1115C>A p.A372D | Missense Mutation (SNP) | VAF 80/379 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781424858; ClinVar: uncertain significance; called by mutect2, varscan2
- ACAN | c.2248G>T p.G750C | Missense Mutation (SNP) | VAF 27/339 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV61370861; called by muse, mutect2
- ACBD4 | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 108/400 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs372896376; called by muse, mutect2, varscan2
- ACIN1 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.561); catalogued as rs748433579; called by muse, mutect2, varscan2
- ACLY | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs141297025, COSV61250109; called by muse, mutect2, varscan2
- ACO2 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 85/482 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as rs746141024; called by muse, mutect2, varscan2
- ACOT1 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 116/819 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs746882222, COSV58574813; called by muse, mutect2, varscan2
- ACOX3 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV100712067; called by mutect2, varscan2
- ACSF3 | c.1158G>T p.Q386H | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV58080486; called by muse, mutect2, varscan2
- ACSL1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 99/378 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55664940; called by muse, mutect2, varscan2
- ACSL4 | c.1294C>A p.L432M (on ENST00000340800 / NM_022977.2; = p.L391M on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/335 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV61614277; called by muse, mutect2, varscan2
- ACSL5 | c.527A>T p.N176I (on ENST00000354273; = p.N232I on NM_016234.3) | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs771314917; called by muse, mutect2, varscan2
- ACTA1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 66/366 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as CM095302, CM095303, COSV64203373; called by muse, mutect2, varscan2
- ACTL6A | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 51/534 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs1331119703; called by muse, mutect2
- ACTL6B | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99355712; called by muse, mutect2, varscan2
- ACTL7A | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs377067877; called by muse, mutect2, varscan2
- ACTRT1 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 141/294 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as rs372401429, COSV100947509; called by muse, mutect2, varscan2
- ADAM23 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 65/495 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1195518457; called by muse, mutect2, varscan2
- ADAM33 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 71/386 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.051); catalogued as COSV62936053; called by muse, mutect2, varscan2
- ADAM8 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs776195089; called by muse, mutect2, varscan2
- ADAMTS14 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1306778495; called by muse, varscan2
- ADAMTS16 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.265); catalogued as COSV56986510; called by muse, mutect2, varscan2
- ADAMTS2 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV51076966; called by muse, mutect2
- ADAMTS20 | c.5632C>T p.R1878* | Nonsense Mutation (SNP) | VAF 115/290 reads (40%) | catalogued as rs749060316, COSV101239404; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2010G>A p.W670* | Nonsense Mutation (SNP) | VAF 13/171 reads (8%) | catalogued as COSV101001172, COSV65897056; called by muse, mutect2
- ADAP2 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 208/375 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV58295172; called by muse, mutect2, varscan2
- ADCK1 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.889); catalogued as COSV99451190; called by muse, mutect2, varscan2
- ADCY1 | c.1894C>A p.P632T | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV52038961; called by muse, mutect2, varscan2
- ADCY4 | c.2540C>A p.P847H | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60251553; called by muse, mutect2, varscan2
- ADCY8 | c.2423A>C p.D808A | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV53929574; called by muse, mutect2, varscan2
- ADCY9 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 90/335 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.246); catalogued as COSV53572751; called by muse, mutect2, varscan2
- ADGRA1 | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66925572; called by muse, mutect2, varscan2
- ADGRA2 | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 127/295 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370345639; called by muse, mutect2, varscan2
- ADGRB1 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV99075407; called by mutect2, varscan2
- ADGRB1 | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 39/418 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as rs757292289, COSV60096964; called by muse, mutect2
- ADGRD1 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs972706610; called by muse, mutect2, varscan2
- ADGRD1 | c.1234del p.H412Tfs*24 | Frame Shift Del (DEL) | VAF 184/344 reads (53%) | catalogued as COSV55450915; called by mutect2, varscan2
- ADGRE2 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 76/481 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs377330707; called by muse, mutect2, varscan2
- ADGRF1 | c.409C>A p.L137I | Missense Mutation (SNP) | VAF 182/430 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV64800201; called by muse, mutect2, varscan2
- ADGRG4 | c.9049C>T p.R3017W | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as rs200523694, COSV54951985; called by muse, mutect2, varscan2
- ADGRG6 | c.3376C>T p.R1126W | Missense Mutation (SNP) | VAF 103/463 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750908671; called by muse, mutect2, varscan2
- ADGRL2 | c.655G>T p.V219F | Missense Mutation (SNP) | VAF 82/424 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54653678; called by muse, varscan2
- ADGRL2 | c.3345T>A p.S1115R (on ENST00000370717 / NM_001366005.1; = p.S1102R on NM_012302.4) | Missense Mutation (SNP) | VAF 110/571 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV54679215; called by muse, mutect2, varscan2
- ADGRV1 | c.11563G>A p.E3855K | Missense Mutation (SNP) | VAF 248/554 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774378608, COSV67980003; called by muse, mutect2, varscan2
- ADORA2A | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs201448773; called by muse, mutect2, varscan2
- ADRA1B | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 103/386 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs187500825; called by muse, mutect2, varscan2
- ADSS1 | c.344A>G p.K115R | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs764190265; called by muse, mutect2, varscan2
- AEBP1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 116/233 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.441); catalogued as rs771996997; called by muse, mutect2, varscan2
- AEBP1 | c.1961G>T p.R654L | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.731); catalogued as rs748402393, COSV56255802; called by mutect2, varscan2
- AEBP1 | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs771502434; called by muse, mutect2, varscan2
- AEBP2 | c.239A>C p.E80A | Missense Mutation (SNP) | VAF 75/335 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as rs1301353752; called by muse, mutect2, varscan2
- AEN | c.966C>G p.D322E | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1429935787; called by muse, mutect2, varscan2
- AFF1 | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 132/261 reads (51%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.874); catalogued as COSV57121468; called by muse, mutect2, varscan2
- AGAP3 | c.1129C>T p.R377W (on ENST00000622464; = p.R413W on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760677803; called by mutect2, varscan2
- AGAP3 | c.1778G>A p.R593Q (on ENST00000622464; = p.R629Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/311 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757190371; called by muse, mutect2, varscan2
- AGBL1 | c.2849C>A p.P950Q | Missense Mutation (SNP) | VAF 102/420 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV66860030; called by muse, mutect2, varscan2
- AGBL3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 77/584 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs531216809; called by muse, mutect2, varscan2
- AGBL3 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 121/497 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs556037195, COSV51955234; called by muse, mutect2, varscan2
- AGO4 | c.2161G>T p.D721Y | Missense Mutation (SNP) | VAF 53/291 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as COSV64616398; called by muse, mutect2, varscan2
- AGRN | c.4733C>T p.P1578L | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1182152353; called by muse, varscan2
- AHNAK | c.5756C>T p.A1919V | Missense Mutation (SNP) | VAF 64/389 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs1462738666; called by muse, mutect2, varscan2
- AKAP17A | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 66/422 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as rs1302375114, COSV58308904; called by muse, varscan2
- AKAP8 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 98/247 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs1246598925; called by muse, mutect2, varscan2
- AKAP9 | c.11307dup p.Q3770Afs*52 (on ENST00000359028; = p.Q3746Afs*52 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 70/307 reads (23%) | catalogued as rs747796926; called by mutect2, varscan2
- AKNA | c.4120C>T p.P1374S | Missense Mutation (SNP) | VAF 169/366 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as rs751639581; called by muse, mutect2, varscan2
- AKNA | c.3491G>A p.R1164Q | Missense Mutation (SNP) | VAF 173/378 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.965); catalogued as rs1050356715; called by muse, mutect2, varscan2
- AKT3 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 71/382 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV55609219; called by muse, mutect2, varscan2
- AL136295.1 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV99841653, COSV99841721; called by muse, mutect2, varscan2
- ALB | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 156/348 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748288891; called by muse, mutect2, varscan2
- ALDH6A1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 99/203 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as COSV100620760; called by muse, mutect2, varscan2
- ALDOA | c.515G>A p.G172E (on ENST00000642816 / NM_001243177.4; = p.G118E on NM_184041.5) | Missense Mutation (SNP) | VAF 57/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs753336912; called by muse, mutect2, varscan2
- ALG14 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 85/429 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1458325257; called by muse, mutect2, varscan2
- ALG1L2 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1315522335; called by muse, mutect2, varscan2
- ALK | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 106/260 reads (41%) | catalogued as rs543234312, COSV66594725; called by muse, mutect2, varscan2
- ALMS1 | c.689C>A p.T230N | Missense Mutation (SNP) | VAF 122/586 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368270555; called by muse, mutect2, varscan2
- ALOX12 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 61/349 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs536094544; called by muse, mutect2, varscan2
- ALPK2 | c.863G>T p.S288I | Missense Mutation (SNP) | VAF 88/428 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.347); catalogued as COSV64494275; called by muse, mutect2, varscan2
- ALPL | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CX132527; called by muse, mutect2, varscan2
- AMFR | c.1884G>A p.M628I | Missense Mutation (SNP) | VAF 91/460 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.026); catalogued as rs1278861908; called by muse, mutect2, varscan2
- AMIGO1 | c.633G>T p.W211C | Missense Mutation (SNP) | VAF 181/383 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV63990378; called by mutect2, varscan2
- AMMECR1 | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 89/366 reads (24%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.007); catalogued as rs752388904; called by mutect2, varscan2
- AMOT | c.2911G>A p.V971I (on ENST00000371959 / NM_001113490.1; = p.V562I on NM_133265.3) | Missense Mutation (SNP) | VAF 38/577 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1030458368; called by muse, mutect2
- ANAPC5 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 36/228 reads (16%) | catalogued as rs1555272548; called by muse, mutect2, varscan2
- ANAPC5 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 45/272 reads (17%) | catalogued as rs1555274841; called by muse, mutect2, varscan2
- ANGPTL4 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV100034996; called by muse, mutect2, varscan2
- ANHX | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 132/319 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs1336637927; called by muse, varscan2
- ANHX | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 81/305 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1000118965; called by muse, mutect2, varscan2
- ANK1 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759562271; called by muse, varscan2
- ANKAR | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 81/412 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs754124669; called by muse, mutect2, varscan2
- ANKFN1 | c.1685G>A p.G562D | Missense Mutation (SNP) | VAF 93/747 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs1361204716; called by muse, mutect2, varscan2
- ANKK1 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs763885896, COSV100392846; called by muse, mutect2, varscan2
- ANKMY1 | c.2266C>T p.R756* | Nonsense Mutation (SNP) | VAF 60/410 reads (15%) | catalogued as rs371478661; called by muse, varscan2
- ANKMY1 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV56035652; called by muse, mutect2
- ANKRD11 | c.7535G>A p.R2512Q | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM150409, COSV99968877; called by muse, varscan2
- ANKRD18A | c.936G>T p.Q312H | Missense Mutation (SNP) | VAF 83/318 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs143206815, COSV68802934; called by muse, mutect2, varscan2
- ANKRD24 | c.951+1G>T p.X317_splice | Splice Site (SNP) | VAF 28/223 reads (13%) | catalogued as COSV99036055; called by muse, mutect2, varscan2
- ANKRD24 | c.2632C>T p.R878W | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1488964166; called by muse, mutect2, varscan2
- ANKRD34B | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 87/504 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs1437451547; called by muse, mutect2, varscan2
- ANKRD35 | c.2332del p.Q778Kfs*23 | Frame Shift Del (DEL) | VAF 174/414 reads (42%) | catalogued as rs782410338; called by mutect2, varscan2
- ANKS1B | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 132/454 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs11109977; called by muse, mutect2, varscan2
- ANKUB1 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 208/473 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs759218065, COSV67167360; called by muse, mutect2, varscan2
- ANKZF1 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 111/416 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV55477664; called by muse, varscan2
- ANKZF1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 89/526 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1448337254, COSV55479327; called by muse, mutect2, varscan2
- ANO1 | c.2349C>A p.I783= | Splice Region (SNP) | VAF 26/271 reads (10%) | catalogued as COSV62449147; called by muse, mutect2, varscan2
- ANO5 | c.2033C>A p.T678N | Missense Mutation (SNP) | VAF 113/619 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100201340; called by muse, mutect2, varscan2
- ANXA13 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs369872747; called by muse, mutect2, varscan2
- ANXA6 | c.2011G>T p.G671C | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400323622; called by muse, mutect2, varscan2
- AOAH | c.1590C>G p.H530Q | Missense Mutation (SNP) | VAF 56/296 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202126000; called by muse, mutect2, varscan2
- AOX1 | c.2747C>A p.S916Y | Missense Mutation (SNP) | VAF 33/616 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65981607; called by muse, mutect2
- AOX1 | c.3941C>T p.A1314V | Missense Mutation (SNP) | VAF 34/457 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV53496718; called by muse, mutect2
- AP1B1 | c.2446G>A p.V816M | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as rs1039709063, COSV58022938; called by muse, mutect2, varscan2
- AP1G2 | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs909305964; called by muse, mutect2
- AP2A1 | c.1272C>A p.I424= | Splice Region (SNP) | VAF 45/173 reads (26%) | catalogued as COSV62817682; called by muse, mutect2, varscan2
- AP2B1 | c.1357G>T p.G453* | Nonsense Mutation (SNP) | VAF 109/539 reads (20%) | catalogued as COSV99251825; called by muse, mutect2, varscan2
- AP4B1 | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 87/418 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56724670, COSV56726953; called by muse, mutect2, varscan2
- AP4B1 | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 90/466 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV56724064; called by muse, mutect2, varscan2
- AP5Z1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as rs372539355, COSV62242583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBA1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); catalogued as rs1272610058; called by muse, mutect2, varscan2
- APBA2 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.366); catalogued as COSV68795106; called by muse, mutect2, varscan2
- APBB1IP | c.1474-1G>T p.X492_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | catalogued as rs1194732523, COSV100882012; called by muse, mutect2, varscan2
- APC2 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 113/290 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1283759882; called by muse, mutect2, varscan2
- APLP1 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 27/409 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.226); catalogued as COSV55707877; called by muse, mutect2
- APLP2 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 199/437 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs778175330; called by muse, mutect2, varscan2
- APOBEC3H | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 67/442 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.911); catalogued as rs769176395, COSV100818874; called by muse, mutect2, varscan2
- APOBR | c.2472G>T p.E824D (on ENST00000431282; = p.E833D on NM_018690.4) | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as COSV60491061; called by muse, mutect2, varscan2
- APP | c.1597C>T p.H533Y | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1287723181; called by muse, mutect2, varscan2
- AQP1 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100311078; called by muse, mutect2, varscan2
- AQP2 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.412); catalogued as rs757280714; called by muse, mutect2, varscan2
- AQP2 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 69/331 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52231559; called by muse, mutect2, varscan2
- ARAF | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 77/588 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV51691478; called by muse, mutect2, varscan2
- ARAP1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 106/318 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1195320881; called by muse, mutect2, varscan2
- ARAP2 | c.4286-1G>T p.X1429_splice | Splice Site (SNP) | VAF 32/568 reads (6%) | catalogued as COSV58285380, COSV58294003; called by muse, mutect2
- AREL1 | c.480T>C p.P160= | Splice Region (SNP) | VAF 24/157 reads (15%) | catalogued as COSV100707596; called by muse, mutect2, varscan2
- ARFGEF2 | c.3901G>A p.V1301I | Missense Mutation (SNP) | VAF 263/542 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.483); catalogued as rs777898909; called by muse, mutect2, varscan2
- ARHGAP24 | c.2047C>T p.L683F (on ENST00000395184 / NM_001025616.3; = p.L590F on NM_031305.3) | Missense Mutation (SNP) | VAF 127/608 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs745618922; called by muse, mutect2, varscan2
- ARHGAP27 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 43/323 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs1478375178; called by muse, mutect2, varscan2
- ARHGAP29 | c.3646C>A p.P1216T | Missense Mutation (SNP) | VAF 98/535 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV53112594; called by muse, mutect2, varscan2
- ARHGAP31 | c.4313G>T p.R1438I | Missense Mutation (SNP) | VAF 79/384 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs570816342; called by muse, mutect2, varscan2
- ARHGAP33 | c.2822G>T p.R941L | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); catalogued as COSV50135707; called by muse, mutect2, varscan2
- ARHGAP35 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 53/459 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as COSV68329338; called by muse, mutect2, varscan2
- ARHGAP40 | c.1144C>A p.L382M | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99717571; called by muse, mutect2
- ARHGAP45 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.278); catalogued as rs992195848; called by muse, varscan2
- ARHGAP6 | c.2749C>T p.R917* (on ENST00000337414 / NM_013427.3; = p.R714* on NM_013423.3) | Nonsense Mutation (SNP) | VAF 64/277 reads (23%) | catalogued as rs771688615; called by muse, mutect2, varscan2
- ARHGDIB | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755743098, COSV56763010; called by muse, varscan2
- ARHGDIB | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56763994; called by muse, varscan2
- ARHGEF1 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61529323; called by muse, mutect2, varscan2
- ARHGEF10 | c.3754G>T p.G1252* (on ENST00000398564; = p.G1227* on NM_014629.4) | Nonsense Mutation (SNP) | VAF 56/183 reads (31%) | catalogued as COSV50682388; called by muse, mutect2, varscan2
- ARHGEF10L | c.3665G>A p.R1222H | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs200620479, COSV99393599; called by muse, mutect2, varscan2
- ARHGEF12 | c.2854G>T p.E952* | Nonsense Mutation (SNP) | VAF 173/425 reads (41%) | catalogued as COSV100754915, COSV100755034; called by muse, mutect2, varscan2
- ARHGEF15 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs753519754; called by muse, mutect2
- ARHGEF15 | c.2092G>A p.V698I | Missense Mutation (SNP) | VAF 51/364 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as rs762341051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF2 | c.2741C>A p.T914N (on ENST00000361247 / NM_001162383.2; = p.T886N on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 136/368 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); catalogued as COSV58107672; called by muse, mutect2, varscan2
- ARHGEF39 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); catalogued as COSV58396564; called by muse, mutect2, varscan2
- ARHGEF6 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 25/552 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.784); catalogued as rs1368379563; called by muse, mutect2
- ARID1A | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as COSV61378125; called by muse, mutect2, varscan2
- ARID2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 68/588 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.67); catalogued as COSV57612787, COSV57617768; called by muse, mutect2, varscan2
- ARID2 | c.4769C>T p.P1590L | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs765441891, COSV100535894; ClinVar: benign; called by muse, mutect2, varscan2
- ARIH2 | c.387+1G>A p.X129_splice | Splice Site (SNP) | VAF 105/525 reads (20%) | catalogued as COSV62705544; called by muse, varscan2
- ARL13B | c.909G>T p.Q303H (on ENST00000394222 / NM_001174150.2; = p.Q196H on NM_144996.4) | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100115478, COSV57398128; called by muse, mutect2, varscan2
- ARL16 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 60/614 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100230694; called by muse, mutect2, varscan2
- ARL2 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 168/405 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55861012; called by muse, varscan2
- ARL6IP4 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 74/324 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV54902029; called by muse, varscan2
- ARL8B | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 194/460 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs137895655; called by muse, mutect2, varscan2
- ARMC12 | c.164-8C>A | Splice Region (SNP) | VAF 113/221 reads (51%) | catalogued as COSV55359114; called by muse, mutect2, varscan2
- ARMC5 | c.1708C>A p.L570M | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51659187; called by muse, mutect2, varscan2
- ARMCX1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 115/232 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV65705210; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs766455775, COSV100772009; called by muse, mutect2, varscan2
- ARPP21 | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99491367; called by muse, mutect2, varscan2
- ARRB1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 201/412 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs779500908, COSV63575629; called by muse, mutect2, varscan2
- ARRDC1 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 136/330 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs754766069; called by mutect2, varscan2
- ARSD | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 97/482 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.55); catalogued as rs150390734, COSV54203447; called by muse, mutect2, varscan2
- ARSF | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 100/548 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100839530; called by mutect2, varscan2
- ARSF | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 124/583 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1017883454; called by muse, mutect2, varscan2
- ARSG | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 53/383 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs373638226; called by muse, mutect2, varscan2
- ARVCF | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 55/343 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); catalogued as rs1243379048; called by muse, mutect2, varscan2
- ARVCF | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 149/321 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as rs1317880150; called by muse, mutect2, varscan2
- ARVCF | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753137512; called by muse, mutect2, varscan2
- ASB1 | c.737A>G p.H246R | Missense Mutation (SNP) | VAF 127/472 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV52827437; called by muse, mutect2, varscan2
- ASB2 | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV73636339; called by muse, mutect2, varscan2
- ASH1L | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 79/547 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1216871119; called by muse, mutect2, varscan2
- ASH2L | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 140/294 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs752712559; called by muse, mutect2, varscan2
- ASIC3 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 120/398 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs771498570; called by muse, mutect2, varscan2
- ASPH | c.793G>T p.V265L | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.111); catalogued as COSV99058654; called by mutect2, varscan2
- ASPM | c.7985C>T p.T2662I | Missense Mutation (SNP) | VAF 235/516 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54126214; called by muse, mutect2, varscan2
- ASPM | c.3425G>A p.R1142H | Missense Mutation (SNP) | VAF 189/434 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769743214; called by muse, mutect2, varscan2
- ASTE1 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 215/470 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs1325827531; called by muse, mutect2, varscan2
- ASXL2 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 169/410 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55463759; called by muse, mutect2, varscan2
- ATAD2 | c.1646+1G>A p.X549_splice | Splice Site (SNP) | VAF 115/489 reads (24%) | catalogued as rs1445595911, COSV54881577; called by muse, mutect2, varscan2
- ATAD2B | c.1946G>A p.S649N | Missense Mutation (SNP) | VAF 121/430 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV53196321; called by muse, mutect2, varscan2
- ATAD3C | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 81/421 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs746072776; called by muse, mutect2, varscan2
- ATE1 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 51/255 reads (20%) | catalogued as rs745899377, COSV56440212; called by muse, mutect2, varscan2
- ATM | c.5362G>T p.G1788C | Missense Mutation (SNP) | VAF 261/578 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV53750977; called by mutect2, varscan2
- ATOH8 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 60/392 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); catalogued as rs959307736; called by muse, mutect2, varscan2
- ATOH8 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 62/428 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.134); catalogued as COSV60402292; called by muse, varscan2
- ATP10B | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 80/384 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773040394, COSV100469313, COSV58778079; called by muse, varscan2
- ATP12A | c.1196A>T p.N399I | Missense Mutation (SNP) | VAF 104/361 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374495757; called by muse, mutect2, varscan2
- ATP1A4 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 82/383 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766792873, COSV63626883; called by muse, mutect2, varscan2
- ATP2B2 | c.1705C>A p.L569M (on ENST00000352432; = p.L535M on NM_001683.5) | Missense Mutation (SNP) | VAF 80/374 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV59488819; called by mutect2, varscan2
- ATP2B2 | c.1327G>A p.A443T (on ENST00000352432; = p.A409T on NM_001683.5) | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV59496531; called by muse, mutect2, varscan2
- ATP2C1 | c.905C>A p.A302D | Missense Mutation (SNP) | VAF 127/532 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60757165; called by muse, mutect2, varscan2
- ATP2C2 | c.2217-7C>A | Splice Region (SNP) | VAF 77/311 reads (25%) | catalogued as rs768399662; called by muse, mutect2, varscan2
- ATP7B | c.4064G>T p.G1355V | Missense Mutation (SNP) | VAF 73/399 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1305262063, CM107542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP7B | c.3347G>T p.S1116I | Missense Mutation (SNP) | VAF 139/619 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV54444784; called by muse, mutect2, varscan2
- ATP8A2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54980835; called by muse, mutect2
- ATP8B2 | c.3300G>A p.W1100* (on ENST00000672630; = p.W1067* on NM_001367934.1 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 130/471 reads (28%) | catalogued as COSV63831603; called by muse, mutect2, varscan2
- ATP9B | c.3276T>C p.G1092= | Splice Region (SNP) | VAF 56/245 reads (23%) | catalogued as rs1322356893; called by muse, mutect2, varscan2
- ATR | c.4961C>G p.A1654G | Missense Mutation (SNP) | VAF 65/624 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV100637641; called by muse, mutect2, varscan2
- ATRX | c.5408G>A p.R1803H | Missense Mutation (SNP) | VAF 203/430 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64873488; called by muse, mutect2, varscan2
- ATRX | c.4441C>T p.R1481W | Missense Mutation (SNP) | VAF 217/496 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100970390, COSV64880586; called by muse, mutect2, varscan2
- ATRX | c.3218G>C p.S1073T | Missense Mutation (SNP) | VAF 118/472 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.952); catalogued as rs781825074; ClinVar: benign; called by muse, mutect2, varscan2
- ATRX | c.2612C>T p.S871L | Missense Mutation (SNP) | VAF 286/642 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1470540200, COSV64878649; called by muse, mutect2, varscan2
- ATXN2L | c.2618C>T p.P873L | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs767093063; called by muse, varscan2
- ATXN2L | c.3106C>T p.P1036S | Missense Mutation (SNP) | VAF 58/632 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.968); catalogued as rs767677257; called by muse, mutect2
- ATXN7L2 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 128/301 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs770557237, COSV60205147; called by muse, mutect2, varscan2
- AUTS2 | c.2645C>T p.T882I | Missense Mutation (SNP) | VAF 47/408 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as rs562632912; called by muse, mutect2, varscan2
- AVL9 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 189/472 reads (40%) | catalogued as rs372188373; called by muse, mutect2, varscan2
- AVPR1B | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.53); catalogued as rs1553289693; called by muse, mutect2, varscan2
- AVPR2 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.088); catalogued as rs782038329, CD972996; called by muse, mutect2, varscan2
- AXIN1 | c.1625G>A p.S542N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV51983852; called by muse, mutect2, varscan2
- AXIN2 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 113/455 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1567752110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GNT6 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV62828757; called by muse, mutect2, varscan2
- B3GNT8 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 146/323 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as rs538172271, COSV54199808; called by muse, mutect2, varscan2
- B3GNT9 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1363845215, COSV54625387; called by muse, mutect2, varscan2
- B3GNT9 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.234); catalogued as COSV54630208; called by muse, mutect2, varscan2
- B4GALNT1 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 232/508 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as rs762763123; called by muse, mutect2, varscan2
- B4GALNT3 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180114936, COSV99843035; called by muse, mutect2, varscan2
- BACH1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 82/687 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs1363977160; called by muse, mutect2, varscan2
- BACH1 | c.1985G>A p.G662D | Missense Mutation (SNP) | VAF 250/594 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.274); catalogued as COSV54519822; called by muse, mutect2, varscan2
- BAHCC1 | c.7009G>A p.V2337M | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.306); catalogued as rs370746071; called by muse, mutect2, varscan2
- BAHD1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); catalogued as COSV69084119; called by muse, mutect2, varscan2
- BAIAP2L2 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV60202492; called by muse, mutect2, varscan2
- BAP1 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1559587924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAN | c.2210-6C>T | Splice Region (SNP) | VAF 150/344 reads (44%) | catalogued as rs766956919; called by muse, mutect2, varscan2
- BCAR1 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 106/232 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765985898, COSV50787908; called by muse, varscan2
- BCKDK | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs757631135; called by muse, mutect2, varscan2
- BCL11B | c.1997C>A p.P666H (on ENST00000357195 / NM_001282237.2; = p.P595H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV61737272; called by muse, mutect2, varscan2
- BCL11B | c.878G>A p.R293H (on ENST00000357195 / NM_001282237.2; = p.R222H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1467278349, COSV100595560; called by muse, varscan2
- BCL11B | c.761C>A p.P254Q (on ENST00000357195 / NM_001282237.2; = p.P183Q on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV61738697; called by muse, varscan2
- BCL11B | c.659G>A p.S220N (on ENST00000357195 / NM_001282237.2; = p.S149N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 206/447 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV100595254, COSV61733498; called by muse, mutect2, varscan2
- BCL2 | c.642G>T p.W214C | Missense Mutation (SNP) | VAF 102/453 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100384309; called by muse, mutect2, varscan2
- BCL6B | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 230/485 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs1261542400; called by muse, mutect2, varscan2
- BCL9L | c.3157T>G p.S1053A | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.503); catalogued as COSV52686755; called by muse, mutect2, varscan2
- BCLAF3 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 229/571 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200297521, COSV61415203; called by muse, mutect2, varscan2
- BCOR | c.4331C>T p.T1444I (on ENST00000378444 / NM_001123385.2; = p.T1410I on NM_017745.6) | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.355); catalogued as rs1203501550; called by muse, varscan2
- BCOR | c.3238+1G>A p.X1080_splice | Splice Site (SNP) | VAF 28/205 reads (14%) | catalogued as COSV60717236; called by muse, mutect2, varscan2
- BCOR | c.365T>C p.M122T | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs369585835; ClinVar: not provided; called by muse, mutect2, varscan2
- BCORL1 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.177); catalogued as rs1013439381, COSV99499414; called by muse, mutect2, varscan2
- BCORL1 | c.3003G>T p.Q1001H | Missense Mutation (SNP) | VAF 124/287 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV54394884; called by muse, mutect2, varscan2
- BCORL1 | c.4870C>A p.L1624I | Missense Mutation (SNP) | VAF 111/230 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs775454892, COSV54397769; called by muse, mutect2, varscan2
- BCR | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as rs773335884; called by muse, mutect2, varscan2
- BCS1L | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 118/347 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773582375; ClinVar: uncertain significance; called by muse, mutect2
- BDNF | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 79/334 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761800998; called by muse, varscan2
- BDNF | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 80/401 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59236944; called by muse, varscan2
- BDP1 | c.5371C>A p.L1791I | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.181); catalogued as COSV62430682; called by muse, mutect2, varscan2
- BHLHE41 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs774499222; called by muse, mutect2, varscan2
- BICRA | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV67604999; called by muse, mutect2, varscan2
- BICRA | c.4061C>T p.P1354L | Missense Mutation (SNP) | VAF 88/230 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1395372795, COSV67605420; called by muse, mutect2, varscan2
- BLZF1 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 304/674 reads (45%) | catalogued as rs1343636472; called by muse, varscan2
- BMP1 | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 122/382 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.27); catalogued as rs748283868; called by muse, mutect2, varscan2
- BMP2K | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 140/565 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55012514; called by muse, varscan2
- BMPER | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 103/484 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV51819841; called by muse, mutect2, varscan2
- BMPR1B | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 155/337 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV52778068; called by muse, mutect2, varscan2
- BNC2 | c.3265C>T p.L1089F | Missense Mutation (SNP) | VAF 152/531 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101035612; called by muse, mutect2, varscan2
- BOC | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780959946, COSV56355042; called by muse, mutect2, varscan2
- BOP1 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1421164627; called by muse, mutect2, varscan2
- BPIFB6 | c.913T>C p.Y305H | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100848515; called by muse, mutect2, varscan2
- BPIFC | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 44/445 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs747702446; called by muse, mutect2
- BRAP | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 31/524 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100554086; called by muse, mutect2
- BRAT1 | c.1314G>T p.Q438H | Missense Mutation (SNP) | VAF 32/321 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as rs1366917458; called by muse, mutect2, varscan2
- BRF1 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 102/316 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1047774060; called by muse, mutect2, varscan2
- BRINP2 | c.1331C>A p.T444N | Missense Mutation (SNP) | VAF 93/470 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV64176421; called by muse, varscan2
- BRPF3 | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 71/418 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs147640469; called by muse, mutect2, varscan2
- BRSK2 | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57549692; called by mutect2, varscan2
- BRSK2 | c.1967C>T p.T656M | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as rs377345773; called by muse, mutect2, varscan2
- BRWD1 | c.6509G>A p.C2170Y | Missense Mutation (SNP) | VAF 100/432 reads (23%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs931966225; called by muse, mutect2, varscan2
- BSN | c.11701C>A p.P3901T | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as COSV56526399; called by muse, mutect2, varscan2
- BSPRY | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 124/242 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs936491020; called by muse, varscan2
- BTAF1 | c.4932G>T p.Q1644H | Missense Mutation (SNP) | VAF 82/444 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV56438959; called by mutect2, varscan2
- BTBD18 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as rs1294716061; called by muse, varscan2
- BTN2A1 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 102/238 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.146); catalogued as rs376402375; called by muse, varscan2
- BUB1 | c.1660G>A p.G554R | Missense Mutation (SNP) | VAF 92/495 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.589); catalogued as COSV57064849; called by muse, mutect2, varscan2
- BUB1B | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 47/398 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs773602222; called by muse, mutect2, varscan2
- C10orf90 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 145/334 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs1554902188; called by muse, varscan2
- C10orf90 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 86/199 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs140913571; called by muse, mutect2, varscan2
- C11orf42 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1311913372; called by muse, mutect2, varscan2
- C15orf39 | c.1331G>A p.S444N | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.82); catalogued as rs763725192; called by muse, mutect2, varscan2
- C16orf46 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 31/316 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV55152637; called by muse, mutect2
- C19orf67 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious, low confidence (0); catalogued as COSV59683628; called by muse, mutect2, varscan2
- C19orf81 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1183268143; called by mutect2, varscan2
- C1QTNF7 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 108/482 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV54851440, COSV54853939; called by muse, varscan2
- C1QTNF8 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV60519906; called by muse, mutect2
- C1orf100 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 177/428 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs376583429; called by muse, varscan2
- C1orf116 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs558076699; called by muse, mutect2, varscan2
- C1orf159 | c.302G>A p.R101H (on ENST00000379339 / NM_001330306.2; = p.R65H on NM_017891.5) | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.818); catalogued as rs370958516; called by muse, mutect2, varscan2
- C1orf94 | c.320A>C p.E107A | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs1442820249; called by muse, mutect2, varscan2
- C20orf194 | c.1266C>T p.R422= | Splice Region (SNP) | VAF 62/493 reads (13%) | catalogued as COSV99330797; called by muse, mutect2, varscan2
- C21orf58 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 63/336 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV52449799; called by muse, mutect2, varscan2
- C2CD3 | c.2603C>G p.S868C | Missense Mutation (SNP) | VAF 175/446 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100486486; called by muse, mutect2, varscan2
- C2CD3 | c.1242C>A p.F414L | Missense Mutation (SNP) | VAF 144/362 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs773235071; called by mutect2, varscan2
- C4BPB | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 77/424 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs1340870109; called by muse, mutect2, varscan2
- C5 | c.2969C>T p.A990V | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as rs1385131482; called by muse, mutect2, varscan2
- C6 | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 102/427 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.329); catalogued as rs750740548; called by muse, mutect2, varscan2
- C6orf89 | c.614C>A p.A205E (on ENST00000373685; = p.A212E on NM_152734.4) | Missense Mutation (SNP) | VAF 62/496 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV62101231; called by mutect2, varscan2
- C8G | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs781139002, COSV56404054; called by muse, mutect2, varscan2
- C8orf74 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs923172574, COSV100262349, COSV100262420; called by muse, mutect2, varscan2
- CABIN1 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 97/446 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.078); catalogued as COSV99573340; called by muse, varscan2
- CABIN1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs751228495; called by muse, varscan2
- CACNA1A | c.2966C>T p.P989L | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.226); catalogued as rs1478798895; called by muse, mutect2, varscan2
- CACNA1B | c.4436C>T p.A1479V | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs752638089; called by muse, varscan2
- CACNA1B | c.5429-1G>A p.X1810_splice | Splice Site (SNP) | VAF 68/493 reads (14%) | catalogued as COSV99499457; called by muse, mutect2, varscan2
- CACNA1B | c.6563G>A p.R2188K | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53125694; called by muse, mutect2, varscan2
- CACNA1C | c.2897G>A p.R966Q | Missense Mutation (SNP) | VAF 147/564 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1394063736, COSV100219856; called by muse, mutect2, varscan2
- CACNA1C | c.5929C>T p.R1977* (on ENST00000399634 / NM_001167625.1; = p.R1906* on NM_000719.7) | Nonsense Mutation (SNP) | VAF 68/405 reads (17%) | catalogued as rs78593627, COSV59773990; called by muse, mutect2, varscan2
- CACNA1D | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 269/627 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55468401; called by muse, mutect2, varscan2
- CACNA1E | c.3512C>T p.A1171V | Missense Mutation (SNP) | VAF 81/319 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs968528269, COSV62382237; called by muse, mutect2, varscan2
- CACNA1E | c.6247C>T p.R2083W (on ENST00000367573 / NM_001205293.3; = p.R2040W on NM_000721.4) | Missense Mutation (SNP) | VAF 92/353 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1337866196, COSV100702838, COSV62389153; called by muse, mutect2, varscan2
- CACNA1G | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 110/232 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429055897; called by muse, varscan2
- CACNA1H | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1316230541; called by muse, mutect2, varscan2
- CACNA1S | c.3526-1G>A p.X1176_splice | Splice Site (SNP) | VAF 77/438 reads (18%) | catalogued as COSV62941132; called by muse, mutect2, varscan2
- CACNA2D3 | c.1479G>T p.K493N | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.158); catalogued as COSV99870587; called by muse, mutect2, varscan2
- CACNA2D4 | c.2143G>T p.D715Y | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV54960621; called by muse, mutect2, varscan2
- CACNB2 | c.1935dup p.R646Tfs*3 (on ENST00000324631 / NM_201596.3; = p.R591Tfs*3 on NM_000724.4) | Frame Shift Ins (INS) | VAF 240/502 reads (48%) | catalogued as rs749359035; called by mutect2, varscan2
- CAD | c.5411G>A p.G1804D | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53024093; called by muse, mutect2, varscan2
- CADPS2 | c.1733G>T p.R578I | Missense Mutation (SNP) | VAF 103/546 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100465670; called by muse, mutect2, varscan2
- CAGE1 | c.811G>A p.A271T (on ENST00000512086; = p.A135T on NM_205864.3) | Missense Mutation (SNP) | VAF 73/390 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV57075528; called by muse, mutect2, varscan2
- CALCOCO2 | c.181-6T>A | Splice Region (SNP) | VAF 50/158 reads (32%) | catalogued as rs1323379889; called by muse, mutect2, varscan2
- CALY | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs980544406; called by muse, mutect2, varscan2
- CAMK1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs757567412, COSV56537583; called by muse, mutect2, varscan2
- CAMK1 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 105/264 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.059); catalogued as rs139097636, COSV56538949; called by muse, mutect2, varscan2
- CAMK1D | c.1039+4C>T | Splice Region (SNP) | VAF 72/433 reads (17%) | catalogued as rs373315791; called by muse, mutect2, varscan2
- CAMKK2 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 65/340 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs778015051; called by muse, mutect2, varscan2
- CAMKMT | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 187/420 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs151250567; called by muse, mutect2, varscan2
- CAMKV | c.1430G>A p.G477D | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.216); catalogued as rs748940995; called by muse, mutect2, varscan2
- CAMSAP1 | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 78/440 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs1263721816; called by muse, varscan2
- CAMSAP3 | c.2423C>T p.P808L | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1269686632, COSV99351852; called by muse, mutect2, varscan2
- CAMTA2 | c.1899C>T p.D633= | Splice Region (SNP) | VAF 109/216 reads (50%) | catalogued as rs746999578; called by muse, mutect2, varscan2
- CAND1 | c.3025G>A p.G1009S | Missense Mutation (SNP) | VAF 51/474 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.46); catalogued as COSV73389563; called by muse, mutect2, varscan2
- CAND2 | c.3308G>A p.G1103D (on ENST00000456430 / NM_001162499.2; = p.G986D on NM_012298.3) | Missense Mutation (SNP) | VAF 79/481 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1429803375, COSV55986596; called by muse, mutect2, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 128/550 reads (23%) | catalogued as rs760711956; called by mutect2, varscan2
- CAP2 | c.210C>A p.D70E | Missense Mutation (SNP) | VAF 160/365 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as COSV57730863; called by muse, mutect2, varscan2
- CARD10 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs370280620; called by muse, mutect2, varscan2
- CARD11 | c.665G>T p.S222I | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100712261; called by muse, mutect2, varscan2
- CARD8 | c.845C>T p.A282V (on ENST00000651546 / NM_001184900.3; = p.A232V on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 135/264 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs750156007; called by muse, mutect2, varscan2
- CARD9 | c.1579G>A p.G527S | Missense Mutation (SNP) | VAF 55/411 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52517546; called by muse, mutect2, varscan2
- CARF | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 89/509 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.053); catalogued as COSV57548074; called by muse, mutect2, varscan2
- CASKIN1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs755469269; called by muse, mutect2, varscan2
- CASP8AP2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 94/416 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.784); catalogued as rs377049861; called by muse, mutect2, varscan2
- CASQ1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 246/571 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.101); catalogued as rs570335623, COSV100927329; called by muse, mutect2, varscan2
- CBLC | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 56/606 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54324298; called by muse, mutect2
- CBLIF | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 110/512 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746888455, COSV57239948; called by muse, mutect2, varscan2
- CC2D2A | c.4314+1G>A p.X1438_splice | Splice Site (SNP) | VAF 20/272 reads (7%) | catalogued as COSV67505466; called by muse, mutect2
- CCAR1 | c.1367G>T p.S456I | Missense Mutation (SNP) | VAF 62/378 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99770496; called by muse, mutect2, varscan2
- CCDC116 | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.708); catalogued as rs763363872; called by muse, mutect2, varscan2
- CCDC126 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56740263; called by muse, mutect2, varscan2
- CCDC141 | c.692G>T p.R231I | Missense Mutation (SNP) | VAF 98/410 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768770173; called by muse, varscan2
- CCDC144A | c.3679G>A p.V1227I | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.009); catalogued as rs776709071; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 147/326 reads (45%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC191 | c.1868A>C p.N623T | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.109); catalogued as COSV99877885; called by muse, mutect2
- CCDC25 | c.324G>T p.Q108H | Missense Mutation (SNP) | VAF 100/500 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV62959691; called by muse, mutect2, varscan2
- CCDC28A | c.478-1G>A p.X160_splice | Splice Site (SNP) | VAF 40/191 reads (21%) | catalogued as rs749042682; called by muse, mutect2, varscan2
- CCDC39 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 104/515 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as CM129164; called by muse, varscan2
- CCDC47 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 389/1180 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs752824382; called by muse, mutect2, varscan2
- CCDC57 | c.1358G>A p.S453N | Missense Mutation (SNP) | VAF 117/736 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV58934022; called by muse, mutect2, varscan2
- CCDC58 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 91/444 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.088); catalogued as rs145038740; called by muse, mutect2, varscan2
- CCDC65 | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 50/444 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372541279; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC65 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 242/579 reads (42%) | catalogued as rs1026893169; called by muse, mutect2, varscan2
- CCDC69 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 47/515 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs142070600; called by muse, mutect2
- CCDC88B | c.4117C>T p.P1373S | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1316284627; called by muse, mutect2, varscan2
- CCDC90B | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99475425; called by muse, mutect2, varscan2
- CCDC91 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 160/351 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs567600037, COSV60347949; called by muse, mutect2, varscan2
- CCDC92 | c.302A>T p.E101V | Missense Mutation (SNP) | VAF 49/642 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53019945; called by muse, mutect2
- CCKBR | c.40G>T p.G14* | Nonsense Mutation (SNP) | VAF 20/288 reads (7%) | catalogued as COSV58100535, COSV58103786; called by muse, mutect2
- CCN1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs774059615, COSV71704306; called by muse, mutect2, varscan2
- CCN4 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs1470209531; called by muse, varscan2
- CCNB1IP1 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 95/362 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62303389, COSV62303483; called by muse, mutect2, varscan2
- CCNB3 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 28/721 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs369531264; called by muse, mutect2
- CCNH | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 141/354 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1194859349; called by muse, mutect2, varscan2
- CCP110 | c.1088A>G p.K363R | Missense Mutation (SNP) | VAF 94/393 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.935); catalogued as rs772985733; called by muse, mutect2, varscan2
- CCR10 | c.851C>A p.A284D | Missense Mutation (SNP) | VAF 97/346 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.091); catalogued as rs757628847; called by muse, mutect2, varscan2
- CCT6B | c.1330T>G p.L444V | Missense Mutation (SNP) | VAF 23/379 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as rs1290830213; called by muse, mutect2
- CD109 | c.1466G>A p.G489D | Missense Mutation (SNP) | VAF 232/541 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.493); catalogued as rs1220517212; called by muse, mutect2, varscan2
- CD1B | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 48/505 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs1345352401; called by muse, mutect2
- CD22 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs150827700, COSV50080707; called by muse, mutect2, varscan2
- CD226 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 20/178 reads (11%) | catalogued as COSV54611744; called by muse, mutect2, varscan2
- CDC42 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 79/348 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV100212667; called by muse, mutect2, varscan2
- CDC42BPA | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 86/417 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV62003387, COSV62003849; called by muse, mutect2, varscan2
- CDC42EP4 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 257/397 reads (65%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs770925940, COSV59962416; called by muse, mutect2, varscan2
- CDC45 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 57/572 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as COSV54248804; called by muse, mutect2, varscan2
- CDCP2 | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 69/145 reads (48%) | catalogued as rs776165502; called by muse, varscan2
- CDH1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 83/742 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55730628; called by muse, mutect2, varscan2
- CDH13 | c.960G>A p.E320= | Splice Region (SNP) | VAF 76/358 reads (21%) | catalogued as rs1408186185; called by muse, mutect2, varscan2
- CDH2 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 84/370 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99298508; called by mutect2, varscan2
- CDH4 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 58/572 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750739023, COSV64655648, COSV64656472; called by muse, mutect2
- CDH6 | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54067959; called by muse, varscan2
- CDK12 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as rs1473672331; called by muse, mutect2, varscan2
- CDK3 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 20/456 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV56915040; called by muse, mutect2
- CDKL2 | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 224/457 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1227891519; called by muse, mutect2, varscan2
- CDKN2A | c.230C>G p.T77S | Missense Mutation (SNP) | VAF 97/348 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.868); catalogued as rs1350680332, COSV100447090, COSV58727079; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDON | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.018); catalogued as COSV54996372; called by muse, mutect2, varscan2
- CDX2 | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.564); catalogued as rs1252421476; called by muse, mutect2, varscan2
- CDYL | c.589C>A p.L197I (on ENST00000328908 / NM_001368125.1; = p.L143I on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/563 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as COSV59361478; called by muse, mutect2
- CDYL2 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 90/419 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.35); catalogued as rs202176613; called by muse, mutect2, varscan2
- CDYL2 | c.357del p.Y120Ifs*27 | Frame Shift Del (DEL) | VAF 48/208 reads (23%) | catalogued as rs1322950628; called by mutect2, varscan2
- CEACAM20 | c.1379C>A p.A460D | Missense Mutation (SNP) | VAF 67/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57603071; called by muse, mutect2, varscan2
- CECR2 | c.2520dup p.N841Qfs*5 (on ENST00000342247 / NM_001290047.2; = p.N658Qfs*5 on NM_001290046.1) | Frame Shift Ins (INS) | VAF 156/302 reads (52%) | catalogued as rs754411618; called by mutect2, varscan2
- CEL | c.1748C>T p.A583V (on ENST00000673714; = p.A580V on NM_001807.6) | Missense Mutation (SNP) | VAF 79/399 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1436252030; called by muse, mutect2, varscan2
- CELA3B | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1486757785; called by muse, mutect2
- CELF3 | c.1271-1G>T p.X424_splice | Splice Site (SNP) | VAF 38/353 reads (11%) | catalogued as COSV51882041; called by muse, mutect2, varscan2
- CELSR1 | c.5699A>G p.K1900R | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs755642751; called by muse, varscan2
- CENPC | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 94/545 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs752067595; called by muse, mutect2, varscan2
- CEP126 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 148/369 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs747330535; called by muse, mutect2, varscan2
- CEP131 | c.2238G>T p.Q746H (on ENST00000269392 / NM_001319228.2; = p.Q743H on NM_014984.4) | Missense Mutation (SNP) | VAF 60/570 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs915104116; called by muse, mutect2
- CEP131 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 140/396 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112208154; called by muse, mutect2, varscan2
- CEP131 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 117/353 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs150344397; called by muse, mutect2, varscan2
- CEP170 | c.3706G>A p.D1236N | Missense Mutation (SNP) | VAF 72/298 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1175636092; called by muse, varscan2
- CEP295 | c.3026C>A p.S1009Y | Missense Mutation (SNP) | VAF 83/433 reads (19%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.509); catalogued as rs1282065048; called by muse, mutect2, varscan2
- CEP55 | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs200933834; called by muse, mutect2, varscan2
- CERCAM | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 99/239 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs762471973, COSV104425629; called by muse, mutect2, varscan2
- CERCAM | c.1248C>A p.D416E | Missense Mutation (SNP) | VAF 172/438 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65710462; called by muse, mutect2, varscan2
- CFAP100 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 111/263 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV61503013; called by muse, mutect2, varscan2
- CFAP20DC | c.2042G>A p.R681Q (on ENST00000482387 / NM_001351530.2; = p.R430Q on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 181/414 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs148126876; called by muse, varscan2
- CFAP251 | c.1350C>A p.S450R | Missense Mutation (SNP) | VAF 60/299 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99996135; called by muse, mutect2, varscan2
- CFAP410 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs752866263; called by muse, mutect2, varscan2
- CFAP43 | c.2298G>T p.K766N | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs762374439; called by muse, mutect2, varscan2
- CFAP47 | c.5185G>C p.V1729L | Missense Mutation (SNP) | VAF 117/544 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV57973343; called by muse, mutect2, varscan2
- CFAP54 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 87/471 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs999647017; called by muse, mutect2, varscan2
- CFAP61 | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 93/429 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55641310; called by muse, mutect2, varscan2
- CFAP61 | c.1670A>G p.H557R | Missense Mutation (SNP) | VAF 48/471 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1419795500; called by muse, varscan2
- CFAP74 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 50/401 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs749164767, COSV54567544; called by muse, varscan2
- CFTR | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 318/715 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1554382604, CD993886; ClinVar: uncertain significance; called by muse, varscan2
- CGN | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 75/144 reads (52%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs751915500, COSV54969464, COSV99641828; called by muse, mutect2, varscan2
- CH25H | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); catalogued as COSV100897398; called by muse, mutect2, varscan2
- CHAMP1 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100778778; called by muse, mutect2
- CHD1L | c.494+1G>A p.X165_splice | Splice Site (SNP) | VAF 75/395 reads (19%) | catalogued as rs942221386; called by muse, varscan2
- CHD5 | c.1382C>A p.T461N | Missense Mutation (SNP) | VAF 116/245 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV99312174; called by muse, mutect2, varscan2
- CHD8 | c.6815C>T p.A2272V (on ENST00000646647 / NM_001170629.2; = p.A1993V on NM_020920.4) | Missense Mutation (SNP) | VAF 210/512 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs745726816, COSV63036893; called by muse, mutect2, varscan2
- CHD9 | c.1361C>G p.T454S | Missense Mutation (SNP) | VAF 138/698 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs759670526; called by muse, mutect2, varscan2
- CHDH | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as rs758542391; called by muse, varscan2
- CHEK1 | c.41C>A p.T14N | Missense Mutation (SNP) | VAF 181/387 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV54023035; called by muse, mutect2, varscan2
- CHGB | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 115/272 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.18); catalogued as rs765715328, COSV100972949; called by muse, mutect2, varscan2
- CHRD | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs781192276; called by muse, mutect2, varscan2
- CHRM3 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs144239896; called by muse, mutect2, varscan2
- CHRM4 | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 33/176 reads (19%) | catalogued as COSV63125974; called by muse, mutect2, varscan2
- CHRNA4 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 156/333 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs77345643; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- CHRNG | c.1460G>A p.G487D | Missense Mutation (SNP) | VAF 84/373 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284148118; called by muse, mutect2, varscan2
- CHST4 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 90/326 reads (28%) | catalogued as rs868620284; called by muse, mutect2, varscan2
- CIC | c.3440C>T p.A1147V | Missense Mutation (SNP) | VAF 165/357 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV99360154; called by muse, mutect2, varscan2
- CIC | c.3830G>A p.R1277H | Missense Mutation (SNP) | VAF 159/345 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as rs778127638, COSV50606213; called by muse, mutect2, varscan2
- CIITA | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 159/652 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs563299137, COSV60855079; called by muse, mutect2, varscan2
- CILP | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56024708, COSV99973792; called by muse, mutect2, varscan2
- CILP2 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 102/216 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV52275580; called by muse, mutect2, varscan2
- CIT | c.5596C>A p.L1866M | Missense Mutation (SNP) | VAF 95/217 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV55867148; called by muse, mutect2, varscan2
- CKAP5 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 86/421 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV56366928; called by muse, mutect2, varscan2
- CLCN7 | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 90/314 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778420950; called by muse, mutect2, varscan2
- CLDN19 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as CD124933; called by muse, mutect2, varscan2
- CLDN4 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs371121791; called by muse, varscan2
- CLDN8 | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 191/435 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs763824206, COSV99729777; called by muse, mutect2, varscan2
- CLEC10A | c.913G>A p.E305K (on ENST00000254868 / NM_182906.4; = p.E281K on NM_006344.4) | Missense Mutation (SNP) | VAF 89/398 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371228002; called by muse, mutect2, varscan2
- CLEC14A | c.600C>A p.S200R | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV60562867; called by muse, mutect2, varscan2
- CLEC17A | c.403+1G>A p.X135_splice | Splice Site (SNP) | VAF 22/305 reads (7%) | catalogued as rs1301871417; called by muse, mutect2
- CLEC3B | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs920902974, COSV56109503; called by muse, mutect2, varscan2
- CLEC4D | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 119/307 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs774598446, COSV55231016; called by muse, mutect2, varscan2
- CLIP3 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs553572365, COSV62111734; called by muse, varscan2
- CLMN | c.2067C>A p.S689R | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs1423926436; called by muse, mutect2
- CLN8 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 108/523 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776409703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLNS1A | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 44/349 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54440722; called by muse, mutect2, varscan2
- CLP1 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 92/357 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as rs768946938; called by muse, mutect2, varscan2
- CLPTM1L | c.1549A>G p.K517E | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs755487218; called by muse, mutect2, varscan2
- CLSPN | c.2675C>A p.P892H | Missense Mutation (SNP) | VAF 95/492 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as COSV99231317; called by muse, mutect2, varscan2
- CNEP1R1 | c.122G>A p.C41Y (on ENST00000427478 / NM_001281789.1; = p.C58Y on NM_153261.5) | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1292772033; called by muse, mutect2, varscan2
- CNGA2 | c.71T>G p.I24S | Missense Mutation (SNP) | VAF 65/549 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as COSV99041502; called by muse, mutect2, varscan2
- CNGA3 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55622943, COSV99737058; called by muse, mutect2, varscan2
- CNGB1 | c.3143C>T p.A1048V | Missense Mutation (SNP) | VAF 141/297 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs755959274, COSV51897054; called by muse, mutect2, varscan2
- CNKSR1 | c.964G>A p.V322I (on ENST00000374253 / NM_001297647.2; = p.V315I on NM_006314.3) | Missense Mutation (SNP) | VAF 55/589 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs199807460; called by muse, mutect2
- CNKSR2 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 48/618 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54249518; called by muse, mutect2
- CNKSR3 | c.1511G>A p.R504K | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.192); catalogued as COSV70480742; called by muse, mutect2, varscan2
- CNNM2 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 122/472 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100881859; called by muse, mutect2, varscan2
- CNOT1 | c.3565C>T p.R1189C | Missense Mutation (SNP) | VAF 156/570 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV55315943; called by muse, varscan2
- CNOT6 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 84/512 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99993432; called by muse, mutect2, varscan2
- CNTN6 | c.1155A>T p.Q385H | Missense Mutation (SNP) | VAF 88/491 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63163053; called by muse, varscan2
- CNTNAP4 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV56699806; called by mutect2, varscan2
- CNTNAP5 | c.931G>T p.G311* | Nonsense Mutation (SNP) | VAF 20/326 reads (6%) | catalogued as COSV101443170, COSV70486567; called by muse, mutect2
- COBL | c.2957G>A p.R986H | Missense Mutation (SNP) | VAF 61/389 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs368670111; called by muse, mutect2, varscan2
- COL10A1 | c.1651G>A p.V551M | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1181038080; called by muse, mutect2
- COL10A1 | c.406G>T p.G136* | Nonsense Mutation (SNP) | VAF 88/317 reads (28%) | catalogued as COSV99684129; called by muse, mutect2, varscan2
- COL11A1 | c.1421del p.P474Qfs*20 | Frame Shift Del (DEL) | VAF 57/158 reads (36%) | catalogued as COSV100617959, COSV62199128; called by mutect2, varscan2
- COL14A1 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 162/853 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs1279837372; called by muse, mutect2, varscan2
- COL17A1 | c.3286G>A p.V1096M | Missense Mutation (SNP) | VAF 93/226 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV62227268; called by muse, varscan2
- COL17A1 | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs192048445; called by muse, mutect2, varscan2
- COL17A1 | c.1347G>T p.W449C | Missense Mutation (SNP) | VAF 90/356 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as rs1489608908; called by muse, mutect2, varscan2
- COL18A1 | c.2741C>T p.P914L (on ENST00000359759 / NM_130444.3; = p.P679L on NM_030582.4) | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs745686627; called by muse, mutect2, varscan2
- COL1A1 | c.4016G>A p.G1339D | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56810190; called by muse, mutect2
- COL1A1 | c.3470G>A p.G1157D | Missense Mutation (SNP) | VAF 178/423 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72656323, CM068181; called by muse, mutect2, varscan2
- COL20A1 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58915540; called by muse, mutect2
- COL20A1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 120/486 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs768498780, COSV58911642; called by muse, mutect2, varscan2
- COL20A1 | c.3620T>C p.V1207A | Missense Mutation (SNP) | VAF 226/442 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs1324592783; called by muse, mutect2, varscan2
- COL21A1 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 68/472 reads (14%) | catalogued as COSV99780558; called by muse, varscan2
- COL24A1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 103/493 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1160863949; called by muse, mutect2, varscan2
- COL3A1 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100482590; called by muse, mutect2, varscan2
- COL3A1 | c.2807G>T p.G936V | Missense Mutation (SNP) | VAF 40/435 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1512454; called by muse, mutect2
- COL4A1 | c.4678G>A p.V1560M | Missense Mutation (SNP) | VAF 117/274 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs754511803; called by muse, mutect2, varscan2
- COL4A2 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1302775228; called by muse, mutect2, varscan2
- COL4A4 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 67/305 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs751085711; called by muse, mutect2, varscan2
- COL4A5 | c.2885C>T p.S962L | Missense Mutation (SNP) | VAF 97/408 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.037); catalogued as COSV100086438; called by muse, mutect2, varscan2
- COL4A5 | c.3632G>T p.G1211V | Missense Mutation (SNP) | VAF 79/404 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960390, COSV100087562; called by muse, mutect2, varscan2
- COL6A1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 66/277 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as rs751779784, COSV62612443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765430501; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, varscan2
- COL6A3 | c.8737G>A p.A2913T | Missense Mutation (SNP) | VAF 142/553 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as CD075361; called by muse, mutect2, varscan2
- COL6A5 | c.748A>T p.N250Y | Missense Mutation (SNP) | VAF 179/404 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55196393; called by muse, mutect2, varscan2
- COL6A5 | c.5185C>T p.Q1729* | Nonsense Mutation (SNP) | VAF 120/672 reads (18%) | catalogued as COSV55212569; called by muse, mutect2, varscan2
- COL7A1 | c.7814G>A p.G2605E | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99866469; called by muse, mutect2, varscan2
- COL8A1 | c.884C>A p.P295H | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV53730093; called by muse, mutect2, varscan2
- COL8A1 | c.1297C>T p.L433F | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.758); catalogued as rs745758051; called by muse, mutect2, varscan2
- COL8A2 | c.281del p.P94Lfs*143 | Frame Shift Del (DEL) | VAF 32/138 reads (23%) | catalogued as rs1277273445; called by mutect2, varscan2
- COLEC11 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as rs760665726; called by muse, mutect2, varscan2
- COLEC11 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.958); catalogued as COSV99030440; called by muse, mutect2
- COLGALT2 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 112/479 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs146207368; called by muse, mutect2, varscan2
- COP1 | c.1551G>T p.W517C | Missense Mutation (SNP) | VAF 66/338 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100442578; called by muse, mutect2, varscan2
- COPS2 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 137/304 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54645315; called by muse, varscan2
- COPS7A | c.343G>C p.V115L | Missense Mutation (SNP) | VAF 119/281 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.102); catalogued as rs773225678; called by muse, mutect2, varscan2
- COQ8A | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs866764988, COSV100825558; called by muse, mutect2, varscan2
- COQ9 | c.897A>C p.Q299H | Missense Mutation (SNP) | VAF 45/500 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1261305809; called by muse, mutect2
- CORO1A | c.161G>T p.S54I | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV54631252; called by muse, mutect2, varscan2
- COX14 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 51/370 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.911); catalogued as rs752679893, COSV58724316; called by muse, mutect2, varscan2
- COX4I2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs769650713; called by muse, varscan2
- COX6A2 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 53/512 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762593457, COSV54931834; called by muse, mutect2, varscan2
- COX7A1 | c.103-7C>T | Splice Region (SNP) | VAF 41/184 reads (22%) | catalogued as rs745444096; called by muse, mutect2, varscan2
- CPAMD8 | c.1441G>T p.G481W (on ENST00000651564; = p.G434W on NM_015692.5) | Missense Mutation (SNP) | VAF 165/316 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760736750; called by muse, mutect2, varscan2
- CPEB1 | c.973C>A p.L325I (on ENST00000617958; = p.L265I on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/274 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.337); catalogued as rs1369653545; called by muse, mutect2, varscan2
- CPEB3 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 95/438 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1211150494, COSV56456831; called by muse, mutect2, varscan2
- CPLANE2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs759019748, COSV65057295; called by muse, varscan2
- CPSF1 | c.2705G>A p.R902H | Missense Mutation (SNP) | VAF 216/466 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as rs782553377; called by muse, varscan2
- CRACD | c.2192G>A p.G731D | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as rs565955897; called by muse, mutect2, varscan2
- CRACR2B | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs973116910, COSV100431698; called by muse, mutect2, varscan2
- CRB2 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100749729; called by muse, mutect2, varscan2
- CRB2 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs766249014; called by muse, mutect2, varscan2
- CRB2 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 35/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs756959702; called by muse, mutect2, varscan2
- CREB3L4 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 131/305 reads (43%) | catalogued as COSV55209199; called by muse, mutect2, varscan2
- CREBBP | c.3271C>T p.R1091C | Missense Mutation (SNP) | VAF 105/525 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52112685; called by muse, mutect2, varscan2
- CREBBP | c.2281G>T p.G761W | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV99273396; called by muse, mutect2, varscan2
- CRELD2 | c.315G>A p.W105* | Nonsense Mutation (SNP) | VAF 58/201 reads (29%) | catalogued as rs764207298; called by muse, mutect2, varscan2
- CROCC2 | c.2569C>T p.Q857* | Nonsense Mutation (SNP) | VAF 155/323 reads (48%) | catalogued as rs1308767957; called by muse, mutect2, varscan2
- CROCC2 | c.2835+7C>T | Splice Region (SNP) | VAF 92/187 reads (49%) | catalogued as rs1327058558; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 126/298 reads (42%) | catalogued as rs756999481; called by mutect2, varscan2
- CRPPA | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 100/517 reads (19%) | catalogued as rs867425685, COSV67907320; called by muse, mutect2, varscan2
- CSMD1 | c.4845G>T p.W1615C (on ENST00000520002; = p.W1614C on NM_033225.6) | Missense Mutation (SNP) | VAF 106/447 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100145282; called by muse, mutect2, varscan2
- CSMD2 | c.3419C>T p.A1140V | Missense Mutation (SNP) | VAF 109/442 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV99588696; called by muse, mutect2, varscan2
- CSMD2 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 142/358 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1449918464, COSV53971807; called by muse, mutect2, varscan2
- CSMD3 | c.5735G>T p.G1912V (on ENST00000297405 / NM_001363185.1; = p.G1808V on NM_052900.3) | Missense Mutation (SNP) | VAF 125/522 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52211110; called by mutect2, varscan2
- CSPP1 | c.659C>A p.P220H (on ENST00000676605; = p.P179H on NM_024790.6) | Missense Mutation (SNP) | VAF 62/370 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs762548335; ClinVar: uncertain significance; called by mutect2, varscan2
- CST1 | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 66/308 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as rs1176747781; called by muse, varscan2
- CT47B1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 82/424 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as rs1253365544; called by muse, mutect2, varscan2
- CTC1 | c.3152G>T p.R1051L | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59852456; called by muse, mutect2, varscan2
- CTDNEP1 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs760550948; called by muse, mutect2, varscan2
- CTNNA2 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 121/559 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV63557736, COSV63565933; called by muse, mutect2, varscan2
- CTNNB1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 25/548 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV62695769, COSV62728765; called by muse, mutect2
- CTNND2 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 75/436 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs772092439, COSV58896689; called by muse, mutect2, varscan2
- CTPS2 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 46/337 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV100826762; called by mutect2, varscan2
- CTPS2 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 104/467 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63723061; called by mutect2, varscan2
- CTSE | c.562G>A p.G188R (on ENST00000360218; = p.G183R on NM_001910.4) | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346183642, COSV63059927; called by muse, mutect2, varscan2
- CTTNBP2 | c.2119C>A p.L707M | Missense Mutation (SNP) | VAF 81/447 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50390826; called by muse, mutect2, varscan2
- CUL3 | c.2096G>A p.R699K | Missense Mutation (SNP) | VAF 142/676 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100024623; called by muse, mutect2, varscan2
- CUL7 | c.4669G>A p.G1557S | Missense Mutation (SNP) | VAF 167/373 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs185741954, COSV99538969; called by muse, mutect2, varscan2
- CUL7 | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 70/240 reads (29%) | catalogued as COSV99538112; called by muse, mutect2, varscan2
- CUL7 | c.2146C>T p.R716W | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs753407734, COSV99538545; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL9 | c.2620C>T p.L874F | Missense Mutation (SNP) | VAF 113/585 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52728342; called by muse, mutect2, varscan2
- CUTC | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 72/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764308496; called by muse, mutect2, varscan2
- CXCL14 | c.193G>A p.E65K (on ENST00000337225; = p.E53K on NM_004887.5) | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755897425; called by muse, varscan2
- CXCL14 | c.146G>A p.S49N (on ENST00000337225; = p.S37N on NM_004887.5) | Missense Mutation (SNP) | VAF 61/332 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs372475912; called by muse, varscan2
- CXCR3 | c.13-3C>T | Splice Region (SNP) | VAF 135/248 reads (54%) | catalogued as rs1356841081; called by muse, mutect2, varscan2
- CXCR4 | c.230G>T p.R77M | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV99602823; called by muse, varscan2
- CYB561A3 | c.437T>A p.M146K | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.084); catalogued as rs755840575; called by muse, mutect2
- CYFIP1 | c.2859G>A p.M953I | Missense Mutation (SNP) | VAF 54/302 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs541567424; called by muse, mutect2, varscan2
- CYFIP2 | c.1041G>T p.E347D | Missense Mutation (SNP) | VAF 231/481 reads (48%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.585); catalogued as COSV100555562; called by muse, mutect2, varscan2
- CYP3A4 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 69/379 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as rs763047916; called by muse, mutect2, varscan2
- CYP4A11 | c.1219A>G p.K407E | Missense Mutation (SNP) | VAF 74/366 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as rs1003098093; called by muse, mutect2, varscan2
- CYP8B1 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 80/417 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs761146146; called by muse, mutect2, varscan2
- CYTH1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 76/600 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs765084883; called by muse, mutect2, varscan2
- DAB2 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 92/500 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1181937725, COSV57918248; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 26/161 reads (16%) | catalogued as rs751187768; called by mutect2, varscan2
- DACT2 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs1420197086; called by muse, mutect2, varscan2
- DAG1 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 65/362 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776025512, COSV100445149; called by muse, mutect2, varscan2
- DAGLB | c.1203C>G p.D401E | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.725); catalogued as rs1461366918; called by muse, mutect2
- DAND5 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1024655539; called by muse, mutect2, varscan2
- DAPK2 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 95/195 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as rs1275026560, COSV56045147; called by muse, mutect2, varscan2
- DAZAP1 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV99244926; called by muse, varscan2
- DBH | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs200430427; called by muse, varscan2
- DBNDD1 | c.305C>T p.T102I (on ENST00000002501 / NM_001042610.3; = p.T122I on NM_024043.3) | Missense Mutation (SNP) | VAF 255/536 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.305); catalogued as rs551879620; called by muse, mutect2, varscan2
- DBNL | c.1214A>G p.D405G (on ENST00000448521 / NM_001014436.3; = p.D406G on NM_014063.7) | Missense Mutation (SNP) | VAF 55/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs770757998; called by muse, mutect2, varscan2
- DBP | c.550+6G>A | Splice Region (SNP) | VAF 34/231 reads (15%) | catalogued as rs1178651674; called by muse, mutect2, varscan2
- DCAF12 | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 76/391 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1359521963; called by muse, mutect2, varscan2
- DCAF12L1 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 67/407 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1449602853, COSV64421269; called by muse, mutect2, varscan2
- DCAF12L2 | c.155T>G p.V52G | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs767303206; called by mutect2, varscan2
- DCAF4L2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV60477323; called by muse, mutect2, varscan2
- DCAF8L2 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV101446064; called by muse, mutect2, varscan2
- DCANP1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 170/427 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.239); catalogued as COSV72345932; called by muse, mutect2, varscan2
- DCC | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 148/606 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59101712; called by mutect2, varscan2
- DCC | c.1525G>T p.G509* | Nonsense Mutation (SNP) | VAF 227/490 reads (46%) | catalogued as rs200772602, COSV59096809; called by muse, mutect2, varscan2
- DCC | c.2600A>G p.N867S | Missense Mutation (SNP) | VAF 238/484 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1023230164; called by muse, mutect2, varscan2
- DCDC2 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 105/437 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as rs1002032199; called by muse, mutect2, varscan2
- DCDC2 | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.145); catalogued as COSV51239737; called by muse, mutect2, varscan2
- DCDC2B | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 131/326 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as rs375062766; called by muse, mutect2, varscan2
- DCLRE1A | c.58A>G p.K20E | Missense Mutation (SNP) | VAF 84/478 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1158738843; called by muse, mutect2, varscan2
- DCP1B | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs556386372; called by muse, mutect2, varscan2
- DCTN4 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 40/590 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69783127; called by muse, mutect2
- DDIT4 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs377049909; called by muse, mutect2, varscan2
- DDX11 | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 133/562 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148168429; ClinVar: likely benign; called by muse, mutect2, varscan2
- DDX19B | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1219161655; called by muse, mutect2, varscan2
- DDX23 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 61/352 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs778024664, COSV57283495; called by muse, mutect2, varscan2
- DDX31 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 103/298 reads (35%) | catalogued as rs753128554, COSV60135762; called by muse, mutect2
- DDX39A | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs1449753991; called by muse, mutect2, varscan2
- DDX3X | c.1085G>T p.R362I (on ENST00000399959; = p.R363I on NM_001356.5) | Missense Mutation (SNP) | VAF 94/452 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV67863004; called by muse, mutect2, varscan2
- DDX51 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs769585293; called by muse, mutect2, varscan2
- DDX56 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs142907294; called by muse, varscan2
- DDX60 | c.4154C>T p.A1385V | Missense Mutation (SNP) | VAF 189/455 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1052793098, COSV67097291; called by muse, mutect2, varscan2
- DEF8 | c.414C>A p.F138L (on ENST00000268676 / NM_207514.3; = p.F77L on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/558 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV51921335; called by muse, mutect2, varscan2
- DELE1 | c.1150-8C>A | Splice Region (SNP) | VAF 66/335 reads (20%) | catalogued as COSV52004036; called by mutect2, varscan2
- DENND1C | c.1436dup p.S480Lfs*56 | Frame Shift Ins (INS) | VAF 24/209 reads (11%) | catalogued as rs775749909; called by mutect2, varscan2
- DENND2A | c.2661G>T p.R887S | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1467108506; called by muse, mutect2, varscan2
- DENND6A | c.743T>C p.I248T | Missense Mutation (SNP) | VAF 128/288 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV60769329; called by muse, varscan2
- DEPDC1B | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 47/262 reads (18%) | catalogued as rs776591200; called by muse, mutect2, varscan2
- DEPTOR | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs747255387, COSV53815986; called by muse, mutect2, varscan2
- DGKD | c.2564dup p.T856Yfs*5 (on ENST00000264057 / NM_152879.3; = p.T812Yfs*5 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 82/195 reads (42%) | catalogued as rs35538077; called by mutect2, varscan2
- DGKK | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 111/448 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV65707976; called by muse, mutect2, varscan2
- DGKZ | c.2875C>T p.L959F (on ENST00000454345 / NM_001105540.2; = p.L771F on NM_003646.4) | Missense Mutation (SNP) | VAF 81/374 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.285); catalogued as rs1565084039; called by muse, mutect2, varscan2
- DHCR24 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763847179; called by muse, varscan2
- DHRS4 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 109/466 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57480793; called by muse, mutect2, varscan2
- DHRS4 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs748632968; called by muse, mutect2, varscan2
- DHRS4L2 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 90/365 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100632556; called by muse, mutect2, varscan2
- DHRSX | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 92/370 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as rs184424531; called by muse, mutect2, varscan2
- DHX16 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 54/588 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs778439722; called by muse, mutect2
- DHX30 | c.1802G>A p.R601Q (on ENST00000445061 / NM_138615.3; = p.R562Q on NM_014966.3) | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777603452; called by muse, mutect2, varscan2
- DHX30 | c.2723G>T p.R908L (on ENST00000445061 / NM_138615.3; = p.R869L on NM_014966.3) | Missense Mutation (SNP) | VAF 130/317 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV53136796; called by muse, mutect2, varscan2
- DHX33 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV50147254; called by muse, mutect2, varscan2
- DHX57 | c.3871C>T p.R1291* | Nonsense Mutation (SNP) | VAF 150/420 reads (36%) | catalogued as rs1196446034, COSV99769169; called by muse, mutect2, varscan2
- DICER1 | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 254/591 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1336108562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIO2 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 60/358 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV70444962; called by muse, mutect2, varscan2
- DIP2A | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760650278, COSV100596210; called by muse, mutect2, varscan2
- DIP2A | c.4077G>A p.M1359I | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.155); catalogued as COSV59472350; called by muse, mutect2
- DIP2B | c.2461C>T p.R821* | Nonsense Mutation (SNP) | VAF 186/425 reads (44%) | catalogued as rs1261122361, COSV56582924; called by muse, mutect2, varscan2
- DIP2C | c.4534C>A p.L1512M | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs1017313683; called by muse, mutect2, varscan2
- DISP2 | c.2923G>A p.A975T | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as rs1467334560; called by muse, mutect2, varscan2
- DLC1 | c.1723G>A p.G575S (on ENST00000276297 / NM_001348081.2; = p.G138S on NM_006094.5) | Missense Mutation (SNP) | VAF 67/310 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs762750959; called by muse, mutect2, varscan2
- DLEC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 245/521 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs753949751, COSV57303794; called by muse, mutect2, varscan2
- DLEC1 | c.3458C>A p.P1153H | Missense Mutation (SNP) | VAF 122/291 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); catalogued as COSV57298675; called by muse, mutect2, varscan2
- DLG3 | c.2128C>T p.R710W (on ENST00000374360 / NM_021120.4; = p.R405W on NM_020730.3) | Missense Mutation (SNP) | VAF 137/285 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1465036476; called by muse, mutect2, varscan2
- DLG5 | c.2722G>A p.V908M | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as rs1351719390; called by muse, mutect2, varscan2
- DLGAP1 | c.1462C>A p.R488S | Missense Mutation (SNP) | VAF 74/323 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59809227; called by muse, mutect2, varscan2
- DLGAP1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 78/330 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100233607; called by muse, mutect2, varscan2
- DLGAP3 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 78/355 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as rs755789996; called by muse, mutect2, varscan2
- DLL3 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 80/312 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1302322736; called by muse, mutect2, varscan2
- DLX5 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV56034793; called by muse, mutect2
- DMD | c.8167A>G p.R2723G | Missense Mutation (SNP) | VAF 41/723 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as CD067533; called by muse, mutect2
- DMRT1 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 85/352 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101206629; called by muse, mutect2, varscan2
- DMRTA2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV68673170; called by muse, varscan2
- DMRTC2 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV99523384; called by muse, mutect2
- DNAAF1 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 178/434 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs375812500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs776082413; called by muse, mutect2, varscan2
- DNAH1 | c.2977G>A p.A993T | Missense Mutation (SNP) | VAF 231/554 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs771568448; called by muse, varscan2
- DNAH10 | c.7667G>T p.R2556I (on ENST00000409039; = p.R2495I on NM_207437.3) | Missense Mutation (SNP) | VAF 103/468 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV68990864, COSV68994001; called by muse, mutect2, varscan2
- DNAH11 | c.2533G>A p.A845T | Missense Mutation (SNP) | VAF 138/320 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs1269684711; called by muse, mutect2, varscan2
- DNAH17 | c.9115G>A p.V3039I | Missense Mutation (SNP) | VAF 65/649 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1361685888; called by muse, mutect2, varscan2
- DNAH17 | c.1906C>T p.H636Y | Missense Mutation (SNP) | VAF 74/605 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777018909; called by muse, mutect2, varscan2
- DNAH2 | c.11588G>T p.R3863L | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV66720564; called by muse, varscan2
- DNAH3 | c.4408G>A p.G1470R | Missense Mutation (SNP) | VAF 76/413 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54511170; called by muse, mutect2, varscan2
- DNAH3 | c.2083C>T p.R695* | Nonsense Mutation (SNP) | VAF 145/326 reads (44%) | catalogued as rs757653495; called by muse, mutect2, varscan2
- DNAH5 | c.12562G>A p.V4188M | Missense Mutation (SNP) | VAF 131/610 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.457); catalogued as rs773314785; called by muse, mutect2, varscan2
- DNAH5 | c.7940C>T p.P2647L | Missense Mutation (SNP) | VAF 179/448 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756865161, COSV54229441; called by muse, varscan2
- DNAH6 | c.1912C>T p.L638F | Missense Mutation (SNP) | VAF 74/390 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs758855367; called by muse, mutect2, varscan2
- DNAH7 | c.6151C>T p.R2051W | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374484303; called by muse, mutect2, varscan2
- DNAH8 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 130/632 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.077); catalogued as rs1194003481; called by muse, mutect2, varscan2
- DNAH8 | c.11359G>A p.G3787R | Missense Mutation (SNP) | VAF 18/467 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868826973; called by muse, mutect2
- DNAH9 | c.12634G>A p.G4212R | Missense Mutation (SNP) | VAF 124/463 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs756969119, COSV52353057, COSV99060924; called by muse, mutect2, varscan2
- DNAJB2 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs552929444; called by muse, mutect2, varscan2
- DNAJC1 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 77/406 reads (19%) | catalogued as rs781026180, COSV65375965; called by muse, mutect2, varscan2
- DNAJC13 | c.2434C>T p.H812Y | Missense Mutation (SNP) | VAF 86/399 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1439889548; called by muse, mutect2, varscan2
- DNAJC13 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 201/446 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs544291506, COSV99608099; called by muse, mutect2, varscan2
- DNAJC17 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as COSV55024705; called by muse, mutect2, varscan2
- DNAJC19 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 134/584 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs550711498; called by muse, mutect2, varscan2
- DNAJC5B | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 81/554 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52535665; called by muse, mutect2, varscan2
- DNHD1 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs1017044947, COSV99600450; called by muse, mutect2, varscan2
- DNM1 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 82/422 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57851690; called by muse, mutect2, varscan2
- DNM1 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 87/360 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs994101485, COSV57854958; called by muse, mutect2, varscan2
- DNM1L | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 147/672 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1230267460; called by muse, mutect2, varscan2
- DNMT1 | c.2827C>A p.P943T | Missense Mutation (SNP) | VAF 108/367 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61577339; called by muse, mutect2, varscan2
15,303 further variants in this file (8,910 protein-altering or splice-affecting, 3,220 silent, 3,173 other) are not listed here.
